Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8324, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8324-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:
Financial Number:

Clinical Diagnosis & History:

female with large right renal mass, radical nephrectomy specimen.

Specimens Submitted:

1: SP: Rt. kidney & adrenal
2: SP: Rt. gonadal vein

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- CHROMOPHOBE RENAL CELL CARCINOMA (9.7 CM). THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE AND ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- 2) VEIN, RIGHT GONADAL; EXCISION:
- UNREMARKABLE VEIN, NEGATIVE FOR TUMOR.

NOTE: CASE REVIEWED AT INTRADEPARTMENTAL CONFERENCE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON THE PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) BY THE PATHOLOGIST WHOSE NAME APPEARS ABOVE MINE, AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1) The specimen is received fresh, labeled "Right Kidney and Adrenal". It consists of a nephrectomy specimen with attached perirenal fat. The ureter is 7.5 cm in length and 0.5 cm in diameter. The renal artery and vein are 1.5 and 1 cm in length and 0.6 and 0.8 cm in diameter. The specimen weighs 530 grams all together and measures 15 x 10 x 8 cm. There is a tumor mass in the middle portion of the specimen measuring 9 x 7.5 x 7.5 cm and it is bulging under the capsule to the lateral side of the specimen. This area is inked. After the perirenal fat is removed, the

[page 2 of 2]
specimen weighs 430 grams. The specimen is bisected and in the middle portion of the kidney, which measures 14, 8 x 7.5 cm, a 9.7 x 9 x 7.5 cm tumor occupying the entire middle portion of the kidney, occluding the hilar area is seen with a tan-yellow, light brown color and areas of cystic degeneration. The tumor grossly involves the capsule, only three calices can be identified in the hilar area. The renal parenchyma measures 3 cm in greatest dimension in the areas which is not involved by the tumor. The tumor shows some multinodularity. Some of these nodules are lighter in color than the surrounding tumor tissue. No definite adrenal gland is identified in the specimen.

Summary of Sections:

SM - surgical margin of artery, vein and ureter
T - tumor
C - capsule overlying the tumor
TK - tumor with normal looking kidney tissue
H - hilar area
K - normal looking kidney

2) The specimen is received in formalin, labeled "Right Gonadal Vein". It consists of a portion of a vein measuring 1.3 cm in length and 0.5 cm in diameter. Entirely submitted in one cassette.

Summary of Sections:

U - undesignated

Histo Stain Results/Comments:

Stain/Procedure Name	Result	Comment
RECUT ADDITIONAL H&E		
RECUT ADDITIONAL H&E		

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	AG	-	M		N
	C	3	M		
	H	2	M		
	K	1	M		
	SM	1	M		
	T	1	1		
	TK	1	1		
	}	-	-		
2	U	1	M		

Source: NCI Genomic Data Commons file fcadb6b5-a332-402e-be94-bb557aabe19c (TCGA-KL-8324.C32C31E3-4491-42F8-9560-715FE982434B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).